Somatic mutation profile of tumor specimen TARGET-30-PALAKE-01A (aliquot TARGET-30-PALAKE-01A-01W) from TARGET case TARGET-30-PALAKE, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 2.4 years (860 days).
Specimen TARGET-30-PALAKE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae28d7da-fe9a-4060-b2f8-72e5361a9728.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALAKE-10A (Blood Derived Normal), aliquot TARGET-30-PALAKE-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f5cf9c7-f970-4678-bafe-b9bfaf36dc22

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 12, Nonsense Mutation 2, Intron 2, Splice Site 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3522C>A p.F1174L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs863225281, COSV66555460, COSV66556325; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTN2 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 104/327 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV63976962, COSV63978975; called by muse, mutect2, varscan2
- AGO3 | c.2449C>T p.H817Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.679); catalogued as COSV55795224; called by muse, mutect2, varscan2
- ARHGEF4 | c.1477C>A p.L493I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.009); catalogued as COSV58126234; called by mutect2, varscan2
- ARSD | c.1655G>T p.R552L | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV66973600; called by muse, mutect2, varscan2
- CD48 | c.73A>C p.S25R | Missense Mutation (SNP) | VAF 86/183 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.868); catalogued as COSV63567245; called by muse, mutect2
- CPEB3 | c.1019C>A p.P340H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV56460174; called by mutect2, varscan2
- CYC1 | c.384C>A p.D128E | Missense Mutation (SNP) | VAF 99/603 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV59644755; called by muse, mutect2, varscan2
- DGLUCY | c.1643G>C p.G548A | Missense Mutation (SNP) | VAF 355/571 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56368276; called by muse, varscan2
- HMOX2 | c.442C>A p.L148I | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54861107; called by mutect2, varscan2
- HOXB13 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV51706747; called by muse, mutect2
- KRT27 | c.952C>A p.L318I | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56972594; called by muse, mutect2, varscan2
- LRBA | c.5435G>A p.R1812H | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770711457; called by mutect2, varscan2
- MAP4 | c.2551G>A p.A851T | Missense Mutation (SNP) | VAF 369/958 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.027); catalogued as COSV53140540; called by mutect2, varscan2
- METTL1 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV55744883; called by muse, mutect2, varscan2
- NOS3 | c.1319dup p.C441Lfs*57 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | catalogued as rs749517498; called by mutect2, varscan2
- NPHP1 | c.1603A>C p.S535R (on ENST00000393272 / NM_207181.4; = p.S536R on NM_000272.5) | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV57210282; called by muse, mutect2
- NT5C2 | c.1308G>T p.M436I | Missense Mutation (SNP) | VAF 31/269 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1355702812, COSV58417994; called by muse, mutect2, varscan2
- OR56A1 | c.567G>C p.R189S | Missense Mutation (SNP) | VAF 109/329 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.297); catalogued as COSV57363301; called by muse, mutect2, varscan2
- PCSK5 | c.2183C>T p.S728L | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV65092954; called by muse, mutect2, varscan2
- PLSCR5 | c.587G>A p.C196Y | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs958037679, COSV71648919; called by mutect2, varscan2
- RANBP2 | c.8032G>T p.E2678* | Nonsense Mutation (SNP) | VAF 22/254 reads (9%) | catalogued as COSV51699422; called by mutect2, varscan2
- SGCG | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV54564432; called by mutect2, varscan2
- SIGLEC9 | c.1345C>A p.Q449K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.421); catalogued as COSV51586336; called by muse, mutect2, varscan2
- SRRM2 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs182545398, COSV57070826; called by muse, mutect2, varscan2
- SYNE1 | c.7431G>T p.L2477F (on ENST00000367255 / NM_182961.4; = p.L2484F on NM_033071.3) | Missense Mutation (SNP) | VAF 122/311 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs748398484, COSV55042657; called by muse, mutect2, varscan2
- TANC1 | c.2992G>A p.D998N | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55091825; called by muse, mutect2, varscan2
- TBXAS1 | c.453G>T p.M151I | Missense Mutation (SNP) | VAF 128/1171 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs756857897, COSV54944728; called by muse, mutect2, varscan2
- TECRL | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 46/391 reads (12%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs753417723, COSV67088982; called by mutect2, varscan2
- TG | c.6622C>T p.R2208W | Missense Mutation (SNP) | VAF 87/998 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs750846435, COSV55065135; called by muse, mutect2, varscan2
- VAV2 | c.994C>T p.P332S (on ENST00000371850 / NM_001134398.2; = p.P327S on NM_003371.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64083696; called by mutect2, varscan2
- ZBTB21 | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 68/136 reads (50%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.727); catalogued as rs775878367, COSV60403069; called by muse, mutect2, varscan2
- ZMYM4 | c.3529-2A>T p.X1177_splice | Splice Site (SNP) | VAF 87/103 reads (84%) | catalogued as COSV58907400, COSV58914190; called by muse, mutect2, varscan2
- AHNAK2 | c.14038_14088del p.P4680_D4696del | In Frame Del (DEL) | VAF 3/27 reads (11%) | called by mutect2*, pindel
- AKNA | c.3413G>T p.R1138I | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by mutect2, varscan2
- ALDOA | c.226C>A p.R76S (on ENST00000642816 / NM_001243177.4; = p.R22S on NM_184041.5) | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.043); called by mutect2, varscan2
- ARHGAP6 | c.1082C>G p.A361G | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.031); called by mutect2, varscan2
- C3orf20 | c.1395G>A p.W465* | Nonsense Mutation (SNP) | VAF 22/97 reads (23%) | called by mutect2, varscan2
- IL16 | c.2407G>T p.A803S (on ENST00000302987 / NM_172217.5; = p.A102S on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRIO | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- ACSF3 | c.393G>A p.A131= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs905316715; called by mutect2, varscan2
- ADCY2 | c.3168G>A p.T1056= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as rs750235029, COSV57886213; called by mutect2, varscan2
- CHERP | c.2175G>A p.R725= | Silent (SNP) | VAF 3/20 reads (15%) | called by mutect2, varscan2
- COL1A1 | c.3852G>T p.L1284= | Silent (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- GUCY2D | c.1509C>T p.I503= | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as COSV54697592; called by muse, mutect2, varscan2
- MCM6 | c.57C>T p.R19= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV51468412; called by mutect2, varscan2
- OPN5 | c.405C>T p.I135= | Silent (SNP) | VAF 76/165 reads (46%) | catalogued as COSV55246581; called by muse, mutect2, varscan2
- PTCHD4 | c.433A>C p.R145= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as COSV59791334; called by muse, mutect2
- SHH | c.171C>A p.G57= | Silent (SNP) | VAF 96/551 reads (17%) | catalogued as COSV51919571, COSV51919579; called by muse, mutect2, varscan2
- THYN1 | c.135C>T p.A45= | Silent (SNP) | VAF 123/602 reads (20%) | catalogued as COSV55541603; called by muse, mutect2, varscan2
- UTP14A | c.270G>T p.L90= | Silent (SNP) | VAF 148/171 reads (87%) | catalogued as COSV64087463; called by muse, mutect2, varscan2
- VPS37C | c.333C>A p.I111= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV57109419; called by mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 6/42 reads (14%) | catalogued as rs201441562; called by pindel, varscan2
- USH1C | c.1284+1112T>A | Intron (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
